Somatic mutation profile of tumor specimen TCGA-27-1831-01A (aliquot TCGA-27-1831-01A-01W-0837-08) from TCGA case TCGA-27-1831, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.9 years (24,447 days).
Specimen TCGA-27-1831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6fe421f-2268-4101-98d7-c9e16e8b033d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1831-10A (Blood Derived Normal), aliquot TCGA-27-1831-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75b37359-9796-4291-bfb0-5dcd60fabb7c

The open-access MAF lists 102 somatic variants for this specimen: 91 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 10, Frame Shift Ins 7, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 2239/5582 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 173/4359 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 22/133 reads (17%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADAMTS4 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); catalogued as COSV63488090; called by muse, mutect2
- APOB | c.11824G>A p.A3942T | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1265296445, COSV51940990; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 23/212 reads (11%) | catalogued as rs3215969; called by mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 35/235 reads (15%) | catalogued as rs745882580; called by mutect2, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CDCP1 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs773715040, COSV56106338, COSV56106516; called by muse, mutect2, varscan2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2, varscan2
- CHRD | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52607805; called by muse, mutect2
- CLDN14 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs142205038; called by muse, varscan2
- COL14A1 | c.2847G>T p.R949S | Missense Mutation (SNP) | VAF 247/326 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52858802; called by muse, mutect2, varscan2
- DAO | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140015394; called by muse, mutect2, varscan2
- DCTN2 | c.593C>G p.T198S (on ENST00000548249 / NM_001261413.2; = p.T203S on NM_006400.4) | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1488629487, COSV63075145; called by muse, varscan2
- DNAH7 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.801); catalogued as COSV100415697; called by muse, mutect2, varscan2
- DNAH9 | c.9712C>T p.L3238F | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs746872029; called by muse, mutect2, varscan2
- EBF3 | c.1266C>G p.I422M (on ENST00000355311 / NM_001375392.1; = p.I413M on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV62476836; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 428/11318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2
- EPHA8 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs769624500, COSV51274070; called by muse, mutect2, varscan2
- EPYC | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 96/291 reads (33%) | catalogued as rs374036301, COSV99664717; called by muse, mutect2, varscan2
- FAT2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377056065; called by muse, mutect2, varscan2
- GANAB | c.2741G>T p.R914L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs140322818; called by muse, mutect2
- GPR83 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145628763, COSV54717571; called by muse, mutect2, varscan2
- IFNE | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 182/368 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV58642144; called by muse, mutect2, varscan2
- KCNS3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 104/595 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.133); catalogued as COSV58407727; called by muse, mutect2, varscan2
- LARP1 | c.3139G>A p.G1047S (on ENST00000518297 / NM_033551.3; = p.G970S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372005840; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 25/147 reads (17%) | catalogued as rs777328830; called by mutect2, varscan2
- MICAL1 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773068171; called by mutect2, varscan2
- MUC16 | c.3983C>T p.T1328M | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1261277009, COSV67475867; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 18/162 reads (11%) | catalogued as rs761123152; called by mutect2, varscan2
- MYO1D | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780229350, COSV59011313; called by muse, mutect2
- NLRP3 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60226917; called by muse, mutect2, varscan2
- NR1H4 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV51849062; called by muse, mutect2, varscan2
- NRCAM | c.2301G>T p.W767C (on ENST00000379028 / NM_001371124.1; = p.W751C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61040539; called by muse, mutect2
- OIT3 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as rs779208918, COSV61826522; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- PDGFRA | c.2840G>C p.S947T | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.481); catalogued as COSV57269987; called by muse, mutect2
- PMPCB | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 141/572 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99970986; called by muse, mutect2, varscan2
- PPBP | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV56019956; called by muse, mutect2, varscan2
- PTPRM | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV59866599; called by muse, mutect2, varscan2
- RAB3D | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 194/652 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs144965675, COSV55791749; called by muse, mutect2, varscan2
- RELN | c.5015G>A p.C1672Y | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59012332; called by muse, mutect2, varscan2
- SDK1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 90/470 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776052768, COSV67356197; called by muse, varscan2
- SERPINE1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 118/552 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs760569885, COSV56169742; called by muse, mutect2, varscan2
- SLC9C2 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.249); catalogued as COSV62946659; called by muse, mutect2, varscan2
- SSTR4 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs368872232, COSV54798287; called by muse, mutect2, varscan2
- TANC2 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs372829353; called by muse, mutect2, varscan2
- TMEM196 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1328050808, COSV68254865; called by muse, mutect2, varscan2
- UBE3C | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 50/930 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV61954185; called by muse, mutect2
- USH2A | c.9950G>A p.R3317H | Missense Mutation (SNP) | VAF 298/447 reads (67%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140746096; called by muse, mutect2, varscan2
- WFS1 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV56989825; called by muse, mutect2, varscan2
- ZNF3 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 32/238 reads (13%) | catalogued as COSV52796105; called by muse, mutect2, varscan2
- ZNF454 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 17/197 reads (9%) | catalogued as rs1277542741; called by muse, mutect2
- ZNF91 | c.2474C>G p.P825R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56085334, COSV56086529; called by muse, mutect2
- ADAM12 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 30/1182 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY10 | c.1527C>A p.S509R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2
- ALOX15B | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AQP3 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARSJ | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.11); called by muse, varscan2
- ATAD2B | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CABYR | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 33/286 reads (12%) | called by muse, mutect2, varscan2
- CCDC146 | c.1694+1G>T p.X565_splice | Splice Site (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- CDC42EP4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2
- CSMD2 | c.7807C>A p.H2603N | Missense Mutation (SNP) | VAF 100/716 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FLNA | c.720+1G>A p.X240_splice | Splice Site (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- GALK2 | c.396C>A p.C132* | Nonsense Mutation (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- GPR161 | c.1350del p.H450Qfs*2 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- IGF2R | c.4888G>T p.D1630Y | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- IQCA1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ITPR2 | c.2849T>G p.I950S | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- KDM6A | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF2B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAS1L | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 81/514 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MCMDC2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, varscan2
- MED1 | c.2322C>A p.S774R | Missense Mutation (SNP) | VAF 38/652 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- MSH4 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2
- MYH15 | c.4797G>T p.R1599S | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10H2 | c.736_745dup p.V249Afs*27 | Frame Shift Ins (INS) | VAF 264/629 reads (42%) | called by mutect2, varscan2
- PRDM15 | c.2618G>T p.C873F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS27 | c.855del p.R285Sfs*47 | Frame Shift Del (DEL) | VAF 9/13 reads (69%) | called by mutect2, varscan2
- RILPL2 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMS2 | c.3151A>T p.R1051* (on ENST00000666250 / NM_001348490.2; = p.R859* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- RPL32 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 21/603 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- RUNDC3B | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- SATL1 | c.1298del p.V433Afs*8 (on ENST00000395409; = p.V620Afs*63 on NM_001012980.2) | Frame Shift Del (DEL) | VAF 37/222 reads (17%) | called by mutect2, pindel, varscan2
- SMAP1 | c.1148G>A p.G383D (on ENST00000370455 / NM_001044305.3; = p.G356D on NM_021940.5) | Missense Mutation (SNP) | VAF 72/303 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SPAG9 | c.3901C>T p.P1301S (on ENST00000262013 / NM_001130528.3; = p.P1287S on NM_003971.6) | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, varscan2
- TCOF1 | c.1303dup p.Q435Pfs*23 (on ENST00000377797 / NM_001135243.1; = p.Q358Pfs*23 on NM_000356.4) | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by mutect2, pindel, varscan2
- XKR4 | c.1488del p.F496Lfs*5 | Frame Shift Del (DEL) | VAF 27/175 reads (15%) | called by mutect2, pindel, varscan2
- ZNF140 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ABCA12 | c.1411C>T p.L471= (on ENST00000272895 / NM_173076.3; = p.L153= on NM_015657.3) | Silent (SNP) | VAF 42/239 reads (18%) | catalogued as rs547232067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG4B | c.6C>T p.D2= | Silent (SNP) | VAF 38/264 reads (14%) | catalogued as rs369272637; called by muse, mutect2, varscan2
- FAM71F1 | c.138G>A p.P46= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as rs758275371, COSV59373399; called by muse, mutect2, varscan2
- GRIN2B | c.3819G>A p.T1273= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1555101910, COSV74206518; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTR1D | c.642C>T p.I214= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV58448451; called by muse, mutect2, varscan2
- LOXL1 | c.1275C>T p.R425= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs368632424; called by muse, mutect2, varscan2
- NBAS | c.2619G>T p.R873= | Silent (SNP) | VAF 15/392 reads (4%) | called by muse, mutect2
- PLXNA4 | c.1929C>T p.G643= | Silent (SNP) | VAF 118/476 reads (25%) | called by muse, mutect2, varscan2
- TLR6 | c.372G>A p.R124= | Silent (SNP) | VAF 49/87 reads (56%) | catalogued as COSV67935447; called by muse, mutect2, varscan2
- TTC29 | c.576C>T p.Y192= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs777478027, COSV57272500; called by muse, mutect2, varscan2
- SLC37A3 | c.*82C>G | 3'UTR (SNP) | VAF 52/280 reads (19%) | called by muse, mutect2, varscan2
